Somatic mutation profile of tumor specimen TCGA-52-7622-01A (aliquot TCGA-52-7622-01A-11D-2122-08) from TCGA case TCGA-52-7622, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.4 years (22,807 days).
Specimen TCGA-52-7622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b020950-8ccf-4c23-b374-15cacb9f0efb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-52-7622-10A (Blood Derived Normal), aliquot TCGA-52-7622-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e93beef-0c6f-426f-90e2-a44c5e846315

The open-access MAF lists 288 somatic variants for this specimen: 213 protein-altering or splice-affecting, 69 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 69, Nonsense Mutation 20, Frame Shift Del 9, Splice Site 5, 3'UTR 2, Splice Region 2, Intron 1, Frame Shift Ins 1, 5'Flank 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1057519799, COSV60641421, COSV60655080; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67960056, COSV67960150; called by muse, mutect2, varscan2
- A2ML1 | c.2486C>A p.S829* | Nonsense Mutation (SNP) | VAF 76/332 reads (23%) | catalogued as rs758305694, COSV100229195, COSV55290676; called by muse, mutect2, varscan2
- ACAD9 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100459308; called by muse, mutect2, varscan2
- ACAN | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100718702; called by muse, varscan2
- ACVR1C | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.506); catalogued as COSV99694873; called by muse, mutect2
- ADAMTS10 | c.1338-1G>T p.X446_splice | Splice Site (SNP) | VAF 15/129 reads (12%) | catalogued as COSV99547165; called by muse, mutect2, varscan2
- ADAMTS16 | c.1084T>A p.L362I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99942057; called by muse, mutect2, varscan2
- ADARB2 | c.1936G>T p.A646S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV101184569; called by muse, mutect2, varscan2
- AKR7A2 | c.563del p.N188Mfs*33 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as COSV99352029; called by mutect2, pindel, varscan2
- AMOT | c.1271C>T p.P424L (on ENST00000371959 / NM_001113490.1; = p.P15L on NM_133265.3) | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100495332; called by muse, mutect2, varscan2
- ANO5 | c.1917G>T p.W639C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV100202028; called by muse, mutect2, varscan2
- ARFGEF2 | c.2132A>T p.Y711F | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as COSV100904367; called by muse, mutect2
- ARMCX2 | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168221; called by muse, mutect2, varscan2
- ASCC3 | c.5450G>T p.R1817L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV100976744, COSV64982124; called by muse, mutect2, varscan2
- ASTE1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as rs1195834117, COSV53907814; called by muse, mutect2, varscan2
- ATF6 | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100909327; called by muse, mutect2, varscan2
- C12orf42 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV100172476; called by muse, mutect2, varscan2
- CACNA1I | c.544G>T p.V182F | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100360944, COSV60810611; called by muse, mutect2, varscan2
- CBX1 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.245); catalogued as COSV99848203; called by muse, mutect2, varscan2
- CDC37 | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99705822; called by muse, mutect2, varscan2
- CDC42BPB | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs377033153, COSV100775525; called by muse, mutect2, varscan2
- CDH12 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66448673; called by muse, mutect2, varscan2
- CDH12 | c.525G>T p.V175= | Splice Region (SNP) | VAF 20/174 reads (11%) | catalogued as COSV66404472, COSV66425487; called by muse, mutect2
- CDH17 | c.1049A>T p.Q350L | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99217733; called by muse, mutect2, varscan2
- CDK6 | c.239T>A p.F80Y | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99721475; called by muse, mutect2
- CFAP61 | c.2924G>T p.R975I | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs755723209, COSV99845768; called by muse, mutect2, varscan2
- CHD3 | c.1421G>T p.C474F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100391389; called by muse, mutect2, varscan2
- CHD3 | c.1422C>G p.C474W | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100391391; called by muse, mutect2, varscan2
- CHST4 | c.376T>A p.W126R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100632897; called by muse, mutect2, varscan2
- CLDN1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.1); catalogued as COSV99790686; called by muse, mutect2
- CLEC6A | c.452G>A p.W151* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV101165677, COSV65986936; called by muse, mutect2, varscan2
- CNBD1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV101575295; called by muse, mutect2, varscan2
- CNKSR2 | c.2083C>A p.P695T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.031); catalogued as COSV54256125, COSV99669199; called by muse, mutect2, varscan2
- CNKSR2 | c.2084C>A p.P695Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV99669206; called by muse, mutect2, varscan2
- CNOT1 | c.5660G>T p.G1887V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99800719; called by mutect2, varscan2
- CNOT1 | c.5659G>T p.G1887* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99800721; called by muse, mutect2, varscan2
- COG4 | c.1937A>T p.Y646F | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV99851108; called by muse, mutect2, varscan2
- CRISPLD1 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100082232; called by muse, mutect2, varscan2
- DCAF4L2 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV100151087; called by muse, mutect2, varscan2
- DNAH5 | c.7240A>T p.K2414* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99451844; called by muse, mutect2, varscan2
- DNAH8 | c.2522T>C p.F841S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100546391; called by muse, mutect2, varscan2
- DNAJC17 | c.317A>C p.Q106P | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV99591772; called by mutect2, varscan2
- DNHD1 | c.1375A>C p.T459P | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV99600573; called by muse, mutect2
- DOCK2 | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.475); catalogued as COSV99913923; called by muse, mutect2, varscan2
- EHF | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140992; called by muse, mutect2, varscan2
- ENOX2 | c.203G>T p.G68V (on ENST00000338144 / NM_001382520.1; = p.G39V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV100584382; called by muse, mutect2, varscan2
- EYS | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs562862906, COSV100676834; called by muse, mutect2, varscan2
- FAM187B | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 5/130 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100220038; called by muse, mutect2
- FAM47C | c.2833C>T p.P945S | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs782240419, COSV100792814; called by muse, mutect2
- FAM90A1 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.487); catalogued as COSV56712638; called by muse, mutect2
- FBN1 | c.6871+1G>A p.X2291_splice | Splice Site (SNP) | VAF 16/90 reads (18%) | catalogued as CS098584, COSV100355870; called by muse, mutect2, varscan2
- FMR1NB | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.095); catalogued as COSV100975577; called by muse, mutect2, varscan2
- FNDC1 | c.5143T>A p.L1715M | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99796256; called by muse, mutect2, varscan2
- FPR3 | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); catalogued as COSV100200807; called by muse, mutect2, varscan2
- FRMD6 | c.804A>C p.L268F (on ENST00000344768 / NM_001267046.2; = p.L260F on NM_152330.4) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1262320201, COSV100656015; called by muse, mutect2, varscan2
- FRMPD4 | c.1867A>G p.R623G | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); catalogued as COSV101043522; called by muse, mutect2
- GIMAP4 | c.787A>T p.I263F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV99750962; called by muse, mutect2, varscan2
- GLIS2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99267710; called by muse, mutect2, varscan2
- GPC3 | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX073794, COSV100893261; called by muse, mutect2, varscan2
- GPHN | c.1444A>G p.I482V (on ENST00000315266 / NM_001377519.1; = p.I515V on NM_020806.5) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV100016920; called by muse, mutect2, varscan2
- GPR174 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99338244; called by muse, mutect2, varscan2
- GPR83 | c.908T>A p.L303H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99703805; called by muse, mutect2, varscan2
- GPRASP1 | c.1989A>T p.R663S | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV100851036; called by muse, mutect2, varscan2
- HAS2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV100392050; called by muse, mutect2, varscan2
- HTATSF1 | c.1560A>C p.E520D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV99511781; called by muse, mutect2, varscan2
- HTR5A | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as COSV99839832, COSV99840010; called by muse, mutect2, varscan2
- IKBKB | c.1102A>T p.T368S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100645772; called by muse, mutect2, varscan2
- IL2RB | c.1557G>T p.Q519H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99345056; called by muse, mutect2, varscan2
- ITGAL | c.1702-2A>T p.X568_splice | Splice Site (SNP) | VAF 23/125 reads (18%) | catalogued as COSV100776297; called by muse, mutect2, varscan2
- JPH3 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs199967240, COSV52465597; called by muse, mutect2, varscan2
- KATNIP | c.4387G>T p.D1463Y | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851570; called by muse, mutect2, varscan2
- KBTBD12 | c.1110C>A p.C370* | Nonsense Mutation (SNP) | VAF 30/193 reads (16%) | catalogued as COSV100675473; called by muse, mutect2, varscan2
- KRTAP27-1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 39/155 reads (25%) | catalogued as COSV101239742; called by muse, mutect2, varscan2
- LAIR2 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV100003368; called by muse, mutect2, varscan2
- LMTK2 | c.803T>A p.L268Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99807276; called by muse, mutect2, varscan2
- LRIT1 | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV100928119; called by muse, mutect2, varscan2
- LRRIQ1 | c.4729G>T p.V1577L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV101280638; called by muse, mutect2, varscan2
- LTBP1 | c.1127A>G p.K376R (on ENST00000404816 / NM_206943.4; = p.K50R on NM_000627.4) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV100617679; called by muse, mutect2, varscan2
- LYST | c.2894C>G p.S965C | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as rs772671228, COSV67714961; called by muse, mutect2, varscan2
- MAGEB18 | c.749A>C p.Q250P | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100305553; called by muse, mutect2, varscan2
- MARS1 | c.2111C>G p.A704G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100007522; called by muse, mutect2, varscan2
- MBNL1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.203); catalogued as rs780538995, COSV56828467, COSV56836247; called by muse, mutect2, varscan2
- MED14 | c.2247T>A p.Y749* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100247557; called by muse, mutect2
- MMP19 | c.719A>T p.H240L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.058); catalogued as COSV100491186; called by muse, mutect2, varscan2
- MRC2 | c.1588C>A p.P530T | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57643249; called by muse, mutect2, varscan2
- MRC2 | c.1589C>A p.P530Q | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100316480; called by muse, mutect2, varscan2
- MRGPRD | c.16A>T p.N6Y | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.496); catalogued as COSV100483045; called by muse, varscan2
- MRGPRD | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV100483047, COSV58423847; called by muse, varscan2
- MROH2B | c.2348T>C p.I783T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV68182401; called by muse, mutect2
- MSR1 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100027630, COSV50507206; called by muse, mutect2, varscan2
- MSR1 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as CM023574, COSV100027633, COSV50507232; called by muse, mutect2, varscan2
- MTCH2 | c.287A>T p.Q96L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100207046; called by muse, mutect2, varscan2
- MUC17 | c.7730G>C p.R2577T | Missense Mutation (SNP) | VAF 94/503 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1343054668, COSV100071103, COSV100074146, COSV60304623; called by muse, mutect2, varscan2
- MUC17 | c.9522G>C p.M3174I | Missense Mutation (SNP) | VAF 108/501 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100074280, COSV60298466; called by muse, mutect2, varscan2
- MUC20 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs1441326700, COSV100291345; called by muse, mutect2, varscan2
- MXRA5 | c.7567G>A p.E2523K | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99478126; called by muse, mutect2, varscan2
- MYCBP2 | c.13643T>C p.M4548T (on ENST00000357337; = p.M4586T on NM_015057.5) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100631041; called by muse, mutect2
- MYCT1 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100924081, COSV65891341; called by muse, mutect2, varscan2
- MYT1L | c.1072C>A p.R358S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.011); catalogued as rs192615880, COSV101221050, COSV101221136; called by muse, mutect2, varscan2
- MZT2B | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV99919875; called by muse, mutect2, varscan2
- NAT10 | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 58/337 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV99140277; called by muse, mutect2, varscan2
- NAV3 | c.1676G>C p.G559A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.108); catalogued as COSV99886689, COSV99893360; called by muse, mutect2, varscan2
- NEK9 | c.983G>T p.R328I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99464289; called by muse, mutect2, varscan2
- NOS1 | c.2737G>C p.G913R | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV100501010; called by muse, mutect2, varscan2
- NOTCH2 | c.4450T>C p.C1484R | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56695938, COSV99865485; called by muse, mutect2, varscan2
- NRIP1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100012877; called by muse, mutect2, varscan2
- OBSCN | c.4766G>T p.R1589L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.154); catalogued as COSV99481823; called by muse, mutect2, varscan2
- OR10G7 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100389995; called by muse, mutect2, varscan2
- OR1L8 | c.799T>C p.Y267H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.997); catalogued as COSV100508601; called by muse, mutect2, varscan2
- OR2M3 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 72/360 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs770339416, COSV101513481; called by muse, mutect2, varscan2
- OR2T8 | c.16T>A p.Y6N | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100178370; called by muse, mutect2, varscan2
- OR4B1 | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100535653; called by muse, mutect2
- OR4D10 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV101597019; called by muse, mutect2, varscan2
- OR4N2 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV100269794; called by muse, mutect2, varscan2
- OR4Q3 | c.283del p.L95Yfs*22 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | catalogued as COSV59177427; called by mutect2, pindel, varscan2
- OR52A1 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV100200533; called by muse, mutect2, varscan2
- OR56B1 | c.181A>T p.N61Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100402669; called by muse, mutect2, varscan2
- OR5P2 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV100271404; called by muse, mutect2, varscan2
- OR9G4 | c.412A>T p.T138S | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100265194; called by muse, mutect2, varscan2
- OXGR1 | c.565T>G p.S189A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.114); catalogued as COSV100037058; called by muse, mutect2, varscan2
- PCDH10 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.419); catalogued as COSV99994070; called by muse, mutect2, varscan2
- PCSK5 | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100950412; called by muse, mutect2, varscan2
- PDGFD | c.421A>T p.K141* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100160056; called by muse, mutect2, varscan2
- PGM2 | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101126608; called by muse, mutect2, varscan2
- PITPNM2 | c.786G>T p.E262D | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99759314; called by muse, mutect2, varscan2
- PLEKHM1 | c.1892A>T p.Q631L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.301); catalogued as COSV101378805; called by muse, mutect2, varscan2
- PLXNA1 | c.4555C>T p.P1519S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as rs1436041982, COSV99303650; called by muse, mutect2
- PLXND1 | c.3478G>T p.E1160* | Nonsense Mutation (SNP) | VAF 24/138 reads (17%) | catalogued as COSV100140113; called by muse, mutect2, varscan2
- PRAG1 | c.331-1G>T p.X111_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100422475; called by muse, mutect2, varscan2
- PRB4 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as rs1177240696, COSV54401034; called by muse, mutect2, varscan2
- PTCHD3 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV101438936; called by muse, mutect2, varscan2
- RAB37 | c.225T>A p.D75E (on ENST00000392613 / NM_001006638.3; = p.D68E on NM_175738.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100463252; called by muse, mutect2
- RAPGEF2 | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100031420; called by muse, mutect2, varscan2
- RAPGEF3 | c.274-2A>T p.X92_splice (on ENST00000389212; = p.X50_splice on NM_006105.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99406575; called by muse, mutect2, varscan2
- RBM34 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100784004, COSV64012744; called by muse, mutect2, varscan2
- RC3H2 | c.388A>T p.M130L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as COSV100106768; called by muse, mutect2, varscan2
- REG3G | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV99709580; called by muse, mutect2, varscan2
- RELN | c.2645C>A p.S882Y | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100634263, COSV59028087; called by muse, mutect2, varscan2
- RNASE13 | c.209A>T p.K70M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV100409616; called by muse, mutect2, varscan2
- RNMT | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100054767; called by muse, mutect2, varscan2
- RPGR | c.2873G>A p.R958K (on ENST00000339363 / NM_001367249.1; = p.R753K on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100140219; called by muse, mutect2, varscan2
- SALL1 | c.3491G>A p.C1164Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV51764193, COSV99175956; called by muse, mutect2, varscan2
- SEPSECS | c.1065G>T p.L355F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.963); catalogued as COSV100258930; called by muse, mutect2, varscan2
- SIRPA | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.991); catalogued as rs757552603, COSV100605278; called by muse, mutect2, varscan2
- SLC17A5 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100867111; called by muse, mutect2
- SLC5A4 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99832039; called by muse, mutect2, varscan2
- SLC7A14 | c.1229T>C p.M410T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99200689; called by muse, mutect2, varscan2
- SLCO4A1 | c.496T>A p.S166T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV53891410; called by muse, mutect2, varscan2
- SLCO4A1 | c.497C>A p.S166* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99414911; called by muse, mutect2, varscan2
- SLITRK4 | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | catalogued as COSV100567431, COSV62023384; called by muse, mutect2, varscan2
- SNX25 | c.489A>T p.R163S | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV99253160; called by muse, mutect2
- SOBP | c.2518A>G p.M840V | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1169143426, COSV100433284; called by muse, mutect2, varscan2
- SORCS1 | c.3031G>T p.E1011* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99542372, COSV99548206; called by muse, mutect2
- SPAG1 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99309248; called by muse, mutect2, varscan2
- SPINT1 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100689141; called by muse, mutect2, varscan2
- SPTA1 | c.4606A>T p.R1536W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100935233; called by muse, mutect2, varscan2
- SPZ1 | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99698232; called by muse, mutect2, varscan2
- STK31 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV100669694; called by muse, mutect2, varscan2
- STRA6 | c.1552T>C p.F518L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV99997447; called by muse, mutect2, varscan2
- STT3A | c.1834A>G p.I612V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.26); catalogued as rs1320040533, COSV101205237, COSV67065351; called by muse, mutect2, varscan2
- SUCLG1 | c.473A>T p.K158I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV101205451; called by muse, mutect2, varscan2
- SUPT20H | c.278G>A p.G93E (on ENST00000350612 / NM_001014286.3; = p.G94E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1416842927, COSV100634759; called by muse, mutect2, varscan2
- SV2C | c.1476T>A p.H492Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV100456508; called by muse, mutect2, varscan2
- SYT3 | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100144209; called by muse, mutect2, varscan2
- TAS2R60 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100223607; called by muse, mutect2, varscan2
- TGM1 | c.2028C>A p.S676R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99253133; called by muse, mutect2, varscan2
- TGM2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as rs768195948, COSV100821692, COSV63931435; called by muse, mutect2, varscan2
- THADA | c.1969A>T p.M657L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs3752354, COSV100369130; called by muse, mutect2, varscan2
- TIAM2 | c.280C>A p.H94N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); catalogued as COSV100019593; called by muse, mutect2, varscan2
- TIMELESS | c.3596G>T p.R1199L | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV57508688, COSV99974163; called by muse, mutect2, varscan2
- TLN1 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs879022300, COSV100147989; called by muse, mutect2
- TLR7 | c.2576C>G p.A859G | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV101027992; called by muse, mutect2, varscan2
- TNXB | c.5100del p.A1701Pfs*4 (on ENST00000647633; = p.A1454Pfs*4 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV64480484; called by mutect2, pindel, varscan2
- TONSL | c.2726C>A p.P909H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV101340279; called by muse, mutect2, varscan2
- TPP2 | c.3518G>A p.W1173* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV101060350; called by muse, mutect2, varscan2
- TRGV4 | c.42T>C p.P14= | Splice Region (SNP) | VAF 10/44 reads (23%) | catalogued as rs563712038; called by muse, mutect2, varscan2
- TRIM32 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100529001, COSV100530478; called by muse, mutect2, varscan2
- TRPC1 | c.1457G>A p.R486Q (on ENST00000476941 / NM_001251845.2; = p.R452Q on NM_003304.4) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs750475343, COSV56426252; called by muse, mutect2, varscan2
- TRPV5 | c.779T>G p.M260R | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99520765; called by muse, mutect2
- UFL1 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990106; called by muse, mutect2, varscan2
- ULK1 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1412523049, COSV100417098; called by muse, mutect2, varscan2
- UNC13A | c.2850G>T p.M950I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99408977; called by muse, mutect2, varscan2
- UNC13C | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99520569, COSV99522995; called by muse, mutect2, varscan2
- UNC5C | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV101497966; called by muse, mutect2, varscan2
- USP26 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63708685; called by muse, mutect2, varscan2
- USP53 | c.1591A>G p.I531V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168465714, COSV99917910; called by muse, mutect2, varscan2
- UTP14A | c.1909G>C p.V637L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100928986; called by muse, mutect2, varscan2
- WDR49 | c.1648G>T p.E550* (on ENST00000308378 / NM_001366158.1; = p.E891* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100393341; called by muse, mutect2, varscan2
- WFIKKN2 | c.1438C>A p.R480S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.355); catalogued as COSV100259797; called by muse, mutect2, varscan2
- WNT7B | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100255098; called by muse, mutect2, varscan2
- ZBTB20 | c.1961G>T p.R654L (on ENST00000474710 / NM_001164342.2; = p.R581L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100614440; called by muse, mutect2, varscan2
- ZFP41 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 38/158 reads (24%) | catalogued as COSV100414739, COSV58087559; called by muse, mutect2, varscan2
- ZIM3 | c.1193A>G p.K398R | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1307890335, COSV99518350; called by muse, mutect2, varscan2
- ZNF236 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs778979549, COSV99470778; called by muse, mutect2, varscan2
- ZNF318 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 51/236 reads (22%) | catalogued as COSV100545962; called by muse, mutect2, varscan2
- ZNF347 | c.1467G>C p.E489D | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100498350; called by muse, mutect2, varscan2
- ZNF749 | c.1884T>A p.S628R | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV100494420, COSV61947362; called by muse, mutect2, varscan2
- ZNF761 | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | catalogued as COSV100483439; called by muse, mutect2, varscan2
- ZNF808 | c.1418A>G p.H473R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168857115, COSV100708083; called by muse, mutect2, varscan2
- ZRSR2 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV100315237; called by muse, mutect2, varscan2
- ZSCAN26 | c.1235A>T p.H412L (on ENST00000623276 / NM_001111039.2; = p.H278L on NM_152736.5) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397737124; called by muse, mutect2, varscan2
- ACACA | c.6073G>T p.V2025L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- ADAM29 | c.1083dup p.P362Tfs*4 | Frame Shift Ins (INS) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- ALMS1 | c.6179_6190delinsC p.Q2060Pfs*2 | Frame Shift Del (DEL) | VAF 18/132 reads (14%) | called by pindel, varscan2*
- ATAD2 | c.2094del p.Q699Rfs*7 | Frame Shift Del (DEL) | VAF 19/111 reads (17%) | called by mutect2, pindel, varscan2
- HPS4 | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- MEOX1 | c.276del p.N93Tfs*104 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- MREG | c.268del p.L90Sfs*15 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- SPATA7 | c.1603del p.E535Kfs*4 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | called by mutect2, varscan2
- TMCC1 | c.948del p.Q317Sfs*13 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | called by mutect2, pindel, varscan2
- TRGV3 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- YEATS4 | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); called by muse, mutect2
- ACE | c.2622C>T p.P874= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs139366898; called by muse, mutect2, varscan2
- ADAMTS12 | c.432G>C p.T144= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100711385, COSV61261713; called by muse, mutect2, varscan2
- AGXT | c.834C>T p.L278= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as CD093828, COSV100280184; called by muse, mutect2, varscan2
- ANKRD34A | c.1089A>T p.R363= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1553761200, COSV100041339; called by muse, mutect2, varscan2
- APPL2 | c.69G>T p.L23= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99314973; called by muse, mutect2, varscan2
- CAMK2A | c.1323C>A p.G441= (on ENST00000348628 / NM_171825.2; = p.G452= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100652069; called by muse, mutect2, varscan2
- CARD8 | c.687G>T p.L229= (on ENST00000651546 / NM_001184900.3; = p.L179= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100751162; called by muse, mutect2, varscan2
- CBLN4 | c.465T>C p.D155= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99290637; called by muse, mutect2, varscan2
- CCBE1 | c.432G>C p.T144= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV101232768, COSV101232850, COSV67949631; called by muse, mutect2, varscan2
- CLCN1 | c.1566G>T p.G522= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100578281; called by muse, mutect2, varscan2
- COG2 | c.1368G>T p.V456= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV100794731; called by muse, mutect2, varscan2
- COL4A2 | c.2934A>G p.P978= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100847418; called by muse, mutect2, varscan2
- CTCF | c.1638C>T p.H546= | Silent (SNP) | VAF 45/181 reads (25%) | catalogued as rs373624045; called by muse, mutect2, varscan2
- CTNNB1 | c.2226C>T p.H742= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs201583088, COSV100846334; called by muse, mutect2, varscan2
- CZIB | c.225C>T p.S75= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs145021398; called by muse, mutect2, varscan2
- DGKI | c.1290G>A p.L430= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99935965; called by muse, mutect2, varscan2
- DNAH8 | c.8766G>A p.R2922= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100546392; called by muse, mutect2
- ELN | c.1551C>G p.P517= | Silent (SNP) | VAF 7/142 reads (5%) | catalogued as rs782808496; called by muse, mutect2
- FCGBP | c.11628A>G p.V3876= | Silent (SNP) | VAF 29/152 reads (19%) | called by muse, mutect2, varscan2
- GAS2L1 | c.795G>A p.E265= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99329604; called by muse, mutect2
- GPR55 | c.231C>G p.L77= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV101235900; called by muse, mutect2, varscan2
- GRID1 | c.1905C>A p.G635= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100025233; called by muse, mutect2, varscan2
- HOXC4 | c.300G>T p.P100= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100324285; called by muse, mutect2, varscan2
- IGF2BP1 | c.528G>A p.Q176= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99288834; called by muse, mutect2, varscan2
- INHBA | c.640C>A p.R214= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV54220683, COSV99638035; called by muse, mutect2, varscan2
- IRX2 | c.1170C>T p.G390= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- ITGA8 | c.1329A>T p.S443= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100959475; called by muse, mutect2, varscan2
- KIF26B | c.2208G>C p.L736= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100832925; called by muse, mutect2, varscan2
- LRIT1 | c.249C>A p.G83= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1426242514, COSV100928121; called by muse, mutect2, varscan2
- MAGEB10 | c.378C>T p.Y126= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100775325; called by muse, mutect2, varscan2
- MAGEC2 | c.18C>T p.G6= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as rs140435962, COSV56000278; called by muse, mutect2, varscan2
- MCF2 | c.2025T>G p.S675= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs545913292, COSV100644923; called by muse, mutect2, varscan2
- MDN1 | c.13626T>C p.D4542= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs750954237, COSV101021570; called by muse, mutect2, varscan2
- MYH11 | c.2148C>A p.P716= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs757340546, COSV100259508, COSV100259613; called by muse, mutect2, varscan2
- NAV3 | c.1032C>A p.T344= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99893356; called by muse, mutect2, varscan2
- NUP205 | c.1092T>A p.I364= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99607292; called by muse, mutect2, varscan2
- OR10K2 | c.96G>T p.L32= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV100149570; called by muse, mutect2
- OR14A16 | c.363T>C p.Y121= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV100713814; called by muse, mutect2, varscan2
- PGR | c.909C>T p.F303= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99678738; called by muse, mutect2, varscan2
- PNMA5 | c.1218T>C p.H406= | Silent (SNP) | VAF 45/155 reads (29%) | catalogued as COSV100721678; called by muse, mutect2, varscan2
- POLA1 | c.3664C>A p.R1222= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100985651; called by mutect2, varscan2
- PPIAL4G | c.255T>C p.D85= | Silent (SNP) | VAF 12/179 reads (7%) | catalogued as COSV101344015; called by muse, mutect2
- PRODH2 | c.1077G>A p.R359= (on ENST00000301175; = p.R283= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV56562273, COSV99995392; called by muse, mutect2, varscan2
- PRR23B | c.450C>A p.A150= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV61493607; called by muse, mutect2, varscan2
- PTPN12 | c.2250A>T p.I750= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as COSV99950535; called by muse, mutect2, varscan2
- PTPRB | c.3717G>T p.V1239= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1205423659, COSV99718185; called by muse, mutect2, varscan2
- RAD51AP2 | c.2814G>T p.G938= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV101208383; called by muse, mutect2, varscan2
- RXFP3 | c.621G>A p.G207= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100347682; called by muse, mutect2, varscan2
- RYR1 | c.7302A>T p.G2434= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100616352; called by muse, mutect2, varscan2
- SACM1L | c.813G>A p.K271= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV66614004; called by muse, mutect2
- SCAP | c.1656A>G p.P552= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99653040; called by muse, mutect2, varscan2
- SEC23B | c.2178A>G p.P726= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV52719349, COSV52724634; called by muse, mutect2, varscan2
- SERPINB3 | c.162G>A p.K54= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as rs751332591, COSV99380044; called by muse, mutect2, varscan2
- SFTPA1 | c.246T>C p.P82= | Silent (SNP) | VAF 37/141 reads (26%) | catalogued as rs775485466, COSV100957097; called by muse, mutect2, varscan2
- SIRPA | c.1134G>C p.V378= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100605277; called by muse, mutect2, varscan2
- SLC9C1 | c.2088C>T p.D696= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV99998349; called by muse, mutect2, varscan2
- TAAR8 | c.321C>T p.H107= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as COSV99257267; called by muse, mutect2, varscan2
- TAB3 | c.474A>G p.Q158= | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as COSV99916478; called by muse, mutect2, varscan2
- TAF1 | c.2949C>A p.A983= (on ENST00000373790 / NM_138923.4; = p.A1004= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/290 reads (16%) | catalogued as COSV99336375; called by muse, mutect2, varscan2
- TMEM132D | c.621G>T p.T207= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV101396847, COSV101398768; called by muse, mutect2
- TMEM161B | c.1059G>C p.G353= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99680651; called by muse, mutect2, varscan2
- TMPRSS11A | c.843C>A p.V281= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs774630361, COSV58359813; called by muse, mutect2, varscan2
- TOGARAM1 | c.4908G>T p.T1636= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100818167, COSV63891852; called by muse, mutect2, varscan2
- TPCN2 | c.153C>T p.V51= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99593769; called by muse, mutect2, varscan2
- VWA7 | c.471C>A p.T157= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100791792, COSV100791834; called by muse, mutect2, varscan2
- XPNPEP3 | c.1014C>T p.C338= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100782356; called by muse, mutect2, varscan2
- ZBTB12 | c.519C>T p.P173= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100977030; called by muse, mutect2, varscan2
- ZNF320 | c.93T>G p.T31= | Silent (SNP) | VAF 13/197 reads (7%) | catalogued as COSV101206897; called by muse, mutect2
- ZNF674 | c.1161T>C p.C387= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV101345050; called by muse, mutect2, varscan2
- ACP4 | chr19:50798435 T>A | 3'Flank (SNP) | VAF 8/63 reads (13%) | catalogued as COSV54517246; called by muse, mutect2, varscan2
- AMER1 | c.*3719C>A | 3'UTR (SNP) | VAF 17/100 reads (17%) | catalogued as COSV100366729; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500189 A>G | 5'Flank (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- C16orf82 | c.1del | 5'UTR (DEL) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- FGFR3 | c.*57C>A | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99602781; called by muse, mutect2, varscan2
- TTN | c.10360+5433C>A | Intron (SNP) | VAF 12/77 reads (16%) | catalogued as COSV60436942; called by muse, mutect2, varscan2
